Gene-level copy-number profile of tumor specimen TCGA-A2-A0YC-01A from TCGA case TCGA-A2-A0YC, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 59.4 years (21,685 days).
Specimen TCGA-A2-A0YC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.bac34a30-d37a-4bd6-a196-ff72ecd07e65.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A2-A0YC-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/77eb1e2d-244b-40ba-8636-78d2fa6459f3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,088; copy number 2: 50,169; copy number 3: 6,553; copy number 7: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A2-A0YC-01A-11D-A107-01): tumor purity 0.66, ploidy 2.03, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:20,008,865–20,319,026, 1 gene, copy number 7 (within-gene range 3–7): SPECC1.
- chr17:20,111,824–20,322,973, 4 genes, copy number 7 (within-gene range 3–7): KCTD9P1, RNU6-258P, AC004702.1, RNU6-1057P.

Autosomal genes at a single copy (total copy number 1): 3,088. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
